Gene-level copy-number profile of tumor specimen TCGA-EO-A1Y5-01A from TCGA case TCGA-EO-A1Y5, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 63.7 years (23,251 days).
Specimen TCGA-EO-A1Y5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.38f48281-d72d-4524-b6f2-4cdfb21c53f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EO-A1Y5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d7b0e98f-727d-49e0-9489-432295ea53bb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 342; copy number 2: 9,333; copy number 3: 26,319; copy number 4: 11,626; copy number 5: 5,855; copy number 6: 4,849; copy number 7: 837; copy number 8: 160; copy number 9: 58; copy number 10: 18; copy number 18: 249; copy number 23: 17; copy number 26: 127; copy number 45: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EO-A1Y5-01A-11D-A160-01): tumor purity 0.81, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,065 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:3,633,029–4,542,346, 29 genes, copy number 7 (within-gene range 5–7): AL121796.1, LINC02171, LINC02600, ADRA2C, OR7E163P, OR7E162P, AC147876.1, AC226119.1, AC226119.2, ALG1L7P, FAM86EP, ENPP7P9, AC226119.3, AC116562.3, RPS3AP16, AC116562.2, AC116562.1, OR7E103P, UNC93B4, OR7E99P, OR7E43P, OTOP1, TMEM128, LYAR, ZBTB49, AC105415.1, NSG1, STX18, STX18-IT1.
- chr4:8,558,725–19,456,994, 184 genes, copy number 7 (broad region; genes not listed).
- chr4:23,755,041–23,904,089, 1 gene, copy number 8 (within-gene range 4–8): PPARGC1A.
- chr4:68,784,618–76,783,253, 176 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr4:88,695,913–89,114,901, 6 genes, copy number 9: NAP1L5, FAM13A-AS1, AC108065.2, AC108065.1, FAM13A, TIGD2.
- chr4:89,410,960–96,213,100, 48 genes, copy number 8 (within-gene range 6–8): AC093866.1, AC097478.4, SNCA, AC097478.1, AC097478.3, AC097478.2, SNCA-AS1, MMRN1, AC105445.1, CCSER1, RN7SKP248, AC093729.1, TMSB4XP8, AC004054.1, AC074124.1, AC110774.1, KRT19P6, AC093810.1, PMPCAP1, AC097520.2, AC097520.1, LNCPRESS2, AC112695.1, GRID2, MTND1P19, AC095059.2, AC095059.1, AC020699.1, AC110800.1, RNA5SP164, ATOH1, AC096746.1, HMGB3P15, SMARCAD1, HPGDS, AC109925.1, RPL35AP11, PDLIM5, AC108067.1, BMPR1B-DT, BMPR1B, UNC5C, AC106881.1, RPL30P6, PDHA2, RNU6-1059P, RNU6-34P, AC096661.1.
- chr4:96,348,734–96,349,038, 1 gene, copy number 8: RN7SKP28.
- chr4:101,023,409–101,348,883, 4 genes, copy number 10: PPP3CA, MIR8066, MIR1255A, FLJ20021.
- chr4:101,640,946–101,649,974, 1 gene, copy number 10: AC084277.1.
- chr8:31,639,222–32,855,666, 1 gene, copy number 26 (within-gene range 3–26): NRG1.
- chr8:32,026,210–38,996,824, 122 genes, copy number 10–26 (within-gene range 3–26) (broad region; genes not listed).
- chr8:39,018,615–39,018,683, 1 gene, copy number 10: SNORD38D.
- chr8:82,862,779–91,398,155, 110 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:91,594,965–91,595,241, 1 gene, copy number 7: RN7SKP231.
- chr13:43,543,918–44,577,147, 24 genes, copy number 7 (within-gene range 5–7): ENOX1-AS1, AL161714.1, AL162713.2, AL162713.1, CCDC122, AL512506.1, LACC1, AL512506.3, AL512506.2, NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1, AL138960.1, SERP2, TUSC8, TSC22D1, AL138960.2, AL139184.1.
- chr19:15,082,211–20,331,517, 298 genes, copy number 7 (broad region; genes not listed).
- chr19:28,790,812–30,957,192, 43 genes, copy number 23–45: MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr20:10,672,695–11,687,323, 14 genes, copy number 7 (within-gene range 4–7): AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1.
- chr20:11,818,821–11,819,091, 1 gene, copy number 7: RN7SKP111.

Autosomal genes at a single copy (total copy number 1): 319. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
